Somatic mutation profile of tumor specimen TCGA-K7-A6G5-01A (aliquot TCGA-K7-A6G5-01A-11D-A30V-10) from TCGA case TCGA-K7-A6G5, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 66.3 years (24,233 days).
Specimen TCGA-K7-A6G5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ed33b5b-cc87-4b53-a00c-48989b0627a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-K7-A6G5-10A (Blood Derived Normal), aliquot TCGA-K7-A6G5-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e6218ff-e47b-45a3-92ce-d98615cde291

The open-access MAF lists 91 somatic variants for this specimen: 60 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 28, Nonsense Mutation 5, Splice Site 3, Frame Shift Ins 3, Frame Shift Del 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>C p.K335T | Missense Mutation (SNP) | VAF 23/106 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- ARHGAP11B | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 104/385 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as COSV70288435; called by muse, mutect2, varscan2
- ASXL2 | c.3321G>T p.M1107I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV55463219; called by muse, mutect2, varscan2
- BMPR1B | c.835A>G p.T279A | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52779693; called by muse, mutect2, varscan2
- BPIFB4 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs751101194, COSV64951607; called by muse, mutect2, varscan2
- C2CD3 | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58090461, COSV58096228; called by mutect2, varscan2
- C4orf17 | c.881-1G>C p.X294_splice | Splice Site (SNP) | VAF 10/174 reads (6%) | catalogued as COSV56745670; called by muse, mutect2
- CAPN11 | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.696); catalogued as COSV67238535; called by muse, mutect2, varscan2
- CD93 | c.122C>A p.S41* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV55667078; called by muse, mutect2, varscan2
- CEP85L | c.304G>T p.V102L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV63825733; called by muse, mutect2, varscan2
- COQ6 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV53179509; called by muse, mutect2, varscan2
- CYP26B1 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50013236; called by muse, mutect2, varscan2
- EFTUD2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs755063056, CM162378, COSV68183922; called by muse, mutect2, varscan2
- EIF4G2 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs756848879, COSV60598286; called by muse, mutect2, varscan2
- EWSR1 | c.11C>G p.T4R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV53324036; called by muse, mutect2, varscan2
- GABRQ | c.1279G>C p.A427P | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64783165; called by muse, mutect2, varscan2
- GGN | c.218T>C p.L73P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV53057870; called by muse, mutect2, varscan2
- GRPEL2 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV57046554; called by muse, mutect2, varscan2
- HERC2 | c.10001T>G p.V3334G | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.265); catalogued as COSV55337229; called by muse, mutect2, varscan2
- HIGD1A | c.235A>G p.M79V | Missense Mutation (SNP) | VAF 101/504 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368330989; called by muse, mutect2, varscan2
- HYAL4 | c.1017G>T p.W339C | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99772214; called by muse, mutect2
- INTS2 | c.3016A>G p.I1006V | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV52154885; called by muse, mutect2, varscan2
- KCNQ5 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs763590853, COSV59654339; called by muse, mutect2, varscan2
- KRT78 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV58852691; called by muse, mutect2
- KRT81 | c.1020G>T p.K340N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59810681; called by muse, mutect2
- LAMC3 | c.2440G>A p.G814R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs529385350, COSV100736074, COSV63089922; called by muse, mutect2, varscan2
- LDHAL6A | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52651483; called by muse, mutect2, varscan2
- LRRC37B | c.1690G>T p.G564* | Nonsense Mutation (SNP) | VAF 123/402 reads (31%) | catalogued as COSV58953585, COSV58954969; called by muse, varscan2
- MAT1A | c.616T>G p.S206A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV64746377; called by muse, mutect2, varscan2
- NCKAP1L | c.1006T>C p.F336L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV53209805; called by muse, mutect2, varscan2
- NELL1 | c.2126G>T p.W709L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54293940, COSV54324050; called by muse, mutect2, varscan2
- NFU1 | c.252G>T p.R84S (on ENST00000410022 / NM_001002755.4; = p.R60S on NM_015700.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV58007014; called by muse, mutect2, varscan2
- NOL6 | c.2432G>A p.S811N | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV53043667; called by muse, mutect2, varscan2
- NOTCH1 | c.2633G>A p.C878Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53072395; called by muse, mutect2, varscan2
- NPTX2 | c.1285C>T p.L429F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV55718184; called by muse, mutect2, varscan2
- OR51I1 | c.316A>G p.I106V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV66508592; called by muse, mutect2, varscan2
- PCDH10 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52095609, COSV52099314; called by muse, mutect2, varscan2
- PLCB4 | c.3310G>T p.E1104* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV53800835, COSV53809927; called by muse, mutect2, varscan2
- POSTN | c.500G>A p.S167N | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV65713792; called by muse, mutect2, varscan2
- PPIG | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53644600; called by muse, mutect2, varscan2
- PRKCQ | c.1613C>A p.T538N | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54115162; called by muse, mutect2, varscan2
- PRUNE2 | c.6847G>A p.D2283N | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV65044219; called by muse, mutect2, varscan2
- PSMA1 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as COSV67166028, COSV67166095; called by muse, mutect2, varscan2
- RAG1 | c.1705G>T p.A569S | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs138101978; called by muse, mutect2, varscan2
- SCN2A | c.3850G>C p.V1284L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51848841; called by mutect2, varscan2
- SETD2 | c.3731C>T p.P1244L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs768083138, COSV57444650; called by muse, mutect2, varscan2
- SEZ6L2 | c.1447C>T p.P483S (on ENST00000308713 / NM_001114099.3; = p.P413S on NM_012410.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV58101459; called by muse, mutect2, varscan2
- SIGLEC9 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | PolyPhen benign (0.034); catalogued as COSV51586262; called by muse, mutect2, varscan2
- SLC47A1 | c.830A>G p.Y277C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766901352, COSV54502655; called by muse, mutect2, varscan2
- TPO | c.2050C>T p.R684C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs771942015, COSV61101971; called by muse, mutect2, varscan2
- TTN | c.65990T>G p.I21997S (on ENST00000591111; = p.I14573S on NM_003319.4) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | PolyPhen probably damaging (0.943); catalogued as COSV60199787; called by muse, mutect2, varscan2
- VPS13C | c.5813T>G p.F1938C (on ENST00000644861 / NM_020821.3; = p.F1895C on NM_017684.5) | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV51322926; called by muse, mutect2
- VSIG4 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.287); catalogued as COSV66074299; called by muse, mutect2, varscan2
- ZNF230 | c.1254dup p.P419Tfs*5 | Frame Shift Ins (INS) | VAF 21/108 reads (19%) | catalogued as rs760202026; called by mutect2, pindel, varscan2
- ALB | c.1428+2_1428+3del p.X476_splice | Splice Site (DEL) | VAF 20/74 reads (27%) | called by pindel, varscan2
- ALB | c.1725dup p.A576Rfs*11 | Frame Shift Ins (INS) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- CBLB | c.168+1del p.X56_splice | Splice Site (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- NSRP1 | c.348_351del p.K116Nfs*28 | Frame Shift Del (DEL) | VAF 50/234 reads (21%) | called by mutect2, pindel, varscan2
- PCDHA7 | c.401del p.P134Qfs*21 | Frame Shift Del (DEL) | VAF 86/285 reads (30%) | called by mutect2, varscan2
- SHANK1 | c.2229_2230dup p.Q744Pfs*7 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.2709G>A p.Q903= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs925829179, COSV53181928; called by muse, mutect2, varscan2
- AFG3L2 | c.1122A>C p.G374= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52316136; called by muse, mutect2, varscan2
- CTDSPL2 | c.1375T>C p.L459= | Silent (SNP) | VAF 24/48 reads (50%) | catalogued as COSV52947277; called by muse, mutect2, varscan2
- EIF4E | c.12C>T p.V4= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs764172724, COSV55188188; called by muse, mutect2, varscan2
- GAN | c.661C>T p.L221= | Silent (SNP) | VAF 43/138 reads (31%) | catalogued as COSV73721150; called by muse, mutect2, varscan2
- GFUS | c.717C>T p.P239= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as COSV55308005; called by muse, mutect2, varscan2
- IL18BP | c.165C>T p.P55= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs369922984; called by muse, mutect2, varscan2
- KIAA0232 | c.1056C>T p.S352= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV56927325; called by muse, mutect2, varscan2
- KIAA1217 | c.165A>G p.S55= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as COSV64609360; called by muse, mutect2, varscan2
- LAMC1 | c.3621G>A p.T1207= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs1261428031, COSV51155596; called by muse, mutect2, varscan2
- LRRC8E | c.33G>A p.T11= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs772109390, COSV60718725; called by muse, mutect2, varscan2
- MAN2B1 | c.3009A>G p.S1003= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV55473540; called by muse, mutect2, varscan2
- MXRA5 | c.306C>T p.L102= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV54229886, COSV99476361; called by muse, mutect2, varscan2
- PADI1 | c.1542C>T p.A514= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV64938913; called by muse, mutect2, varscan2
- PDE3A | c.1128C>A p.A376= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV62977896, COSV62983592; called by muse, mutect2, varscan2
- PRDM9 | c.1332A>G p.P444= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV57010070; called by muse, mutect2, varscan2
- PTPN2 | c.213C>A p.A71= | Silent (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- SCN1B | c.327C>T p.T109= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV52894813; called by muse, mutect2, varscan2
- SPANXC | c.216C>A p.A72= | Silent (SNP) | VAF 299/443 reads (67%) | catalogued as COSV62842044; called by muse, mutect2, varscan2
- SPRR1B | c.165G>A p.E55= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV61067894; called by mutect2, varscan2
- TFAP2E | c.1212C>T p.A404= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV64697237; called by muse, mutect2, varscan2
- TLN2 | c.3696A>G p.P1232= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV60892316; called by muse, mutect2, varscan2
- VPS72 | c.312G>T p.P104= | Silent (SNP) | VAF 33/127 reads (26%) | catalogued as rs752210930, COSV63166765, COSV63166797; called by muse, mutect2, varscan2
- WNT2 | c.210C>T p.A70= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs139486726; called by muse, mutect2, varscan2
- ZCCHC2 | c.2649T>G p.P883= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as COSV54039662; called by muse, mutect2, varscan2
- ZNF362 | c.1032C>G p.P344= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV65031712; called by muse, mutect2, varscan2
- ZNF608 | c.4284C>T p.S1428= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV60439813; called by muse, mutect2, varscan2
- ZNF804A | c.426T>C p.V142= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV56459534; called by muse, mutect2, varscan2
- ABCA1 | c.720+2709T>G | Intron (SNP) | VAF 11/47 reads (23%) | catalogued as COSV101036906; called by muse, mutect2, varscan2
- FBLN1 | c.1698-9567G>T | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as rs373139240; called by muse, mutect2, varscan2
- PRR34 | n.296C>A | RNA (SNP) | VAF 5/15 reads (33%) | catalogued as COSV61549287; called by muse, mutect2, varscan2
